Somatic mutation profile of tumor specimen TCGA-D3-A5GN-06A (aliquot TCGA-D3-A5GN-06A-11D-A27K-08) from TCGA case TCGA-D3-A5GN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 22.5 years (8,231 days).
Specimen TCGA-D3-A5GN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71cfba65-55ac-4067-8f87-d4ecc3d70afe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A5GN-10A (Blood Derived Normal), aliquot TCGA-D3-A5GN-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36d63814-ffc7-4341-8247-0e6aed5a2b1b

The open-access MAF lists 579 somatic variants for this specimen: 372 protein-altering or splice-affecting, 193 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 344, Silent 193, Nonsense Mutation 21, Intron 5, RNA 4, Splice Site 3, Splice Region 3, 3'UTR 3, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PTEN | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs587780004, COSV100911304, COSV64289791; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751477326, CM102507, COSV52661381, COSV52721872, COSV52783879; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.7526C>T p.P2509L (on ENST00000272895 / NM_173076.3; = p.P2191L on NM_015657.3) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs900221778, COSV55961281; called by muse, mutect2, varscan2
- ABCB5 | c.3551C>T p.S1184L (on ENST00000404938 / NM_001163941.2; = p.S739L on NM_178559.6) | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867855026, COSV51718775; called by muse, mutect2, varscan2
- ABTB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs746001680, COSV54394527; called by muse, mutect2, varscan2
- ACSM3 | c.1448C>G p.S483C | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55503685; called by muse, mutect2, varscan2
- ADAM18 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs757164906, COSV55853643; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262222420, COSV55006266; called by muse, mutect2
- ADGRB2 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as rs773249211, COSV57077958, COSV99926475; called by muse, mutect2, varscan2
- ADGRF1 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); catalogued as COSV64800785, COSV64801326; called by muse, mutect2, varscan2
- ADGRV1 | c.3142A>G p.R1048G | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV67993676; called by muse, mutect2, varscan2
- ADRA1B | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as rs762712089, COSV60703629; called by muse, mutect2, varscan2
- AFAP1L2 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs752359432, COSV58418013; called by muse, mutect2, varscan2
- AFTPH | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99480706; called by muse, mutect2, varscan2
- AK5 | c.1411G>A p.E471K (on ENST00000354567 / NM_174858.3; = p.E445K on NM_012093.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as COSV60979814; called by muse, mutect2, varscan2
- ALMS1 | c.11216C>T p.P3739L | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.331); catalogued as rs1057064646, COSV52519844; called by muse, mutect2, varscan2
- ALPK1 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV51590637; called by muse, mutect2, varscan2
- ANO10 | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.367); catalogued as COSV52735388; called by muse, mutect2
- ANO9 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs7395065; called by muse, mutect2, varscan2
- APLP1 | c.1672G>A p.G558S (on ENST00000221891 / NM_001024807.3; = p.G557S on NM_005166.4) | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.795); catalogued as COSV55706417; called by muse, varscan2
- APOO | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs369973145, COSV64870573; called by muse, mutect2, varscan2
- ARHGAP24 | c.1252C>T p.L418F (on ENST00000395184 / NM_001025616.3; = p.L325F on NM_031305.3) | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV51992810; called by muse, mutect2, varscan2
- ARID5B | c.2924C>T p.S975L | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV54428213; called by muse, mutect2, varscan2
- ARSJ | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59539456; called by muse, mutect2, varscan2
- ASGR2 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as COSV54691308; called by muse, mutect2, varscan2
- ASTN2 | c.1172G>A p.G391E (on ENST00000313400 / NM_001365069.1; = p.G340E on NM_014010.5) | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57811550; called by muse, mutect2, varscan2
- ASTN2 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs1265432305, COSV100527343, COSV57808036; called by muse, mutect2, varscan2
- ASXL1 | c.2873C>T p.S958L | Missense Mutation (SNP) | VAF 70/119 reads (59%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.012); catalogued as rs763638795, COSV60108812, COSV60119704; called by muse, mutect2, varscan2
- ATXN1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs867470111, COSV55222946; called by muse, mutect2, varscan2
- ATXN10 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606276, COSV53300093; called by muse, mutect2, varscan2
- BAIAP2 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.779); catalogued as rs1425310031, COSV58338918; called by muse, mutect2, varscan2
- BDKRB1 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145002930, COSV53706253; called by muse, mutect2, varscan2
- BPIFA3 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV64926185; called by muse, mutect2, varscan2
- BRD8 | c.3269C>T p.S1090F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs1050334314, COSV99648358; called by muse, mutect2, varscan2
- BTBD3 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1229968225, COSV54779135, COSV99655599; called by muse, mutect2, varscan2
- C12orf4 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV54209184; called by muse, mutect2, varscan2
- C12orf50 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV53898231; called by muse, mutect2, varscan2
- C2CD2L | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV60884667; called by muse, mutect2, varscan2
- C5 | c.4403C>T p.P1468L | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56331423; called by muse, mutect2, varscan2
- C6 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as rs778044260, COSV54706799; called by muse, mutect2
- C8orf34 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV57410790; called by muse, mutect2
- CA2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs143666045; called by muse, mutect2, varscan2
- CACNA1I | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60816599; called by muse, mutect2
- CACNA1S | c.2932G>A p.G978R | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs760596943, COSV62942897; called by muse, mutect2, varscan2
- CACNA2D1 | c.3010C>T p.H1004Y (on ENST00000356253 / NM_001366867.1; = p.H992Y on NM_000722.4) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1441701658, COSV62390009; called by muse, mutect2
- CALD1 | c.683T>C p.L228S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV100724426, COSV62652835; called by muse, mutect2, varscan2
- CAMTA2 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.997); catalogued as rs1358934234, COSV61837525; called by muse, mutect2, varscan2
- CARD16 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 96/197 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.444); catalogued as COSV65213365; called by muse, mutect2, varscan2
- CBFA2T3 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.954); catalogued as COSV51931893; called by muse, mutect2, varscan2
- CCDC25 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62959361; called by muse, mutect2, varscan2
- CCDC39 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs772280012, COSV56491945; called by muse, mutect2, varscan2
- CCER1 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs867467733, COSV62648405; called by muse, mutect2, varscan2
- CCNJ | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as COSV56444263; called by muse, mutect2, varscan2
- CCT8L2 | c.1290G>T p.L430F | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); catalogued as COSV63463620; called by muse, mutect2, varscan2
- CD2 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65644780; called by muse, mutect2, varscan2
- CDH20 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53016461; called by muse, mutect2, varscan2
- CDH6 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV54063332; called by muse, mutect2
- CDHR2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV99991580; called by muse, mutect2, varscan2
- CDKL5 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs1064794671, COSV66112626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDKN2A | c.235dup p.T79Nfs*41 | Frame Shift Ins (INS) | VAF 24/44 reads (55%) | catalogued as COSV58699247; called by mutect2, pindel, varscan2
- CEACAM16 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs531707985, COSV69188213; called by muse, mutect2, varscan2
- CELA3B | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV100448740, COSV61405330; called by muse, mutect2, varscan2
- CEP57L1 | c.787T>A p.S263T | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.142); catalogued as COSV61246065; called by muse, mutect2, varscan2
- CEP89 | c.2020G>T p.E674* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV59867170; called by muse, mutect2, varscan2
- CES1 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1457637324, COSV100828674; called by muse, mutect2, varscan2
- CFAP65 | c.4116G>A p.W1372* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV58558971, COSV58565578; called by muse, mutect2, varscan2
- CHGB | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV66761520; called by muse, mutect2, varscan2
- CHGB | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.132); catalogued as COSV66761525; called by muse, mutect2, varscan2
- CHRNA5 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55140222; called by muse, mutect2, varscan2
- CIAO3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV52403312; called by muse, mutect2, varscan2
- CLDN3 | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101230846; called by muse, mutect2, varscan2
- CLDN3 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101230847; called by muse, mutect2, varscan2
- CMKLR1 | c.474G>A p.M158I (on ENST00000312143 / NM_001142344.2; = p.M156I on NM_004072.3) | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs769403375, COSV56441372; called by muse, mutect2, varscan2
- CMTR2 | c.1757C>T p.S586L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1567504539, COSV57603779; called by muse, mutect2, varscan2
- CMYA5 | c.718A>T p.I240F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV71409000; called by muse, mutect2, varscan2
- CMYA5 | c.9899G>A p.G3300D | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV71409002; called by muse, mutect2, varscan2
- CNN3 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54733321; called by muse, mutect2, varscan2
- COG4 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs758395513, COSV60424803; called by muse, mutect2
- COL1A1 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.085); catalogued as rs764315746, COSV56808797; called by muse, mutect2, varscan2
- COL3A1 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58591812, COSV58595226; called by muse, mutect2, varscan2
- COL4A1 | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 123/202 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as rs866989381, COSV65430867; called by muse, mutect2, varscan2
- COPA | c.1207C>A p.Q403K | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.021); catalogued as COSV54108319; called by muse, mutect2
- CPNE5 | c.886A>T p.K296* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV55199354; called by muse, mutect2, varscan2
- CPSF6 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV57018103; called by muse, mutect2, varscan2
- CR1L | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV54330616, COSV54332702; called by muse, mutect2
- CRNN | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 98/146 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV55123021, COSV55123485; called by muse, mutect2, varscan2
- CRTC3 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs1171190438, COSV51599951; called by muse, mutect2, varscan2
- CSMD2 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs757085822, COSV53891958; called by muse, mutect2, varscan2
- CSMD3 | c.5501C>T p.S1834F (on ENST00000297405 / NM_001363185.1; = p.S1730F on NM_052900.3) | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52096194; called by muse, mutect2, varscan2
- CSN3 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as COSV59244837; called by muse, mutect2
- CXCL13 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV54493189; called by muse, mutect2, varscan2
- CYLC1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); catalogued as rs1236706921, COSV61410187; called by muse, mutect2, varscan2
- CYP2C18 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as rs768785722, COSV53669603; called by muse, mutect2, varscan2
- CYP2U1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60548108; called by muse, mutect2, varscan2
- D2HGDH | c.1008T>A p.F336L | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV58323029; called by muse, mutect2, varscan2
- DCAF12L1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0.028); catalogued as rs868353872, COSV100948149, COSV64421461; called by muse, mutect2, varscan2
- DDX46 | c.2891C>T p.A964V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.145); catalogued as COSV100844872; called by muse, mutect2, varscan2
- DGKI | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs760167594, COSV55937658; called by muse, mutect2, varscan2
- DIDO1 | c.6152C>T p.S2051F | Missense Mutation (SNP) | VAF 145/269 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as COSV56632338; called by muse, mutect2, varscan2
- DIO2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs371030555; called by muse, mutect2, varscan2
- DLL4 | c.1877C>T p.T626I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51069708; called by muse, mutect2, varscan2
- DNAAF4 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745975234, COSV58251147; called by muse, mutect2, varscan2
- DNAH10 | c.5951C>T p.S1984F (on ENST00000409039; = p.S1923F on NM_207437.3) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV68999903; called by muse, mutect2, varscan2
- DNAH2 | c.10531G>A p.E3511K | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66725318; called by muse, mutect2, varscan2
- DNAH8 | c.9610G>A p.D3204N | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs867281706, COSV59429139, COSV59478340; called by muse, mutect2, varscan2
- DNMBP | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60631676; called by muse, mutect2, varscan2
- DOCK11 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52246310; called by muse, mutect2, varscan2
- DOCK9 | c.3529C>T p.Q1177* (on ENST00000376460 / NM_001366676.2; = p.Q1178* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | catalogued as COSV59634965; called by muse, mutect2, varscan2
- DPYD | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV64611901; called by muse, mutect2, varscan2
- DSC1 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV57141426; called by muse, mutect2, varscan2
- DSG1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57138758; called by muse, mutect2, varscan2
- ECT2 | c.808C>T p.P270S (on ENST00000392692 / NM_001349098.2; = p.P239S on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51693158; called by muse, mutect2, varscan2
- EFHB | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55552545; called by muse, mutect2, varscan2
- EHBP1L1 | c.1331G>C p.G444A | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV58574663; called by muse, mutect2, varscan2
- ELFN2 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 48/229 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1346318921, COSV68746209; called by muse, mutect2, varscan2
- ELMO1 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV60320742; called by muse, mutect2, varscan2
- ELMOD1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV56192781; called by muse, mutect2
- ENTPD3 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 60/102 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57196043; called by muse, mutect2, varscan2
- EP300 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.006); catalogued as COSV54342942; called by muse, mutect2, varscan2
- ERC2 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55656130; called by muse, mutect2, varscan2
- ERN2 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1164116918, COSV56837267; called by muse, mutect2, varscan2
- EYA4 | c.1712G>A p.G571E (on ENST00000531901 / NM_001301013.1; = p.G565E on NM_004100.5) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62059055; called by muse, mutect2, varscan2
- FAAH2 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66510924; called by muse, mutect2, varscan2
- FAM135B | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV52748604; called by muse, mutect2, varscan2
- FAM135B | c.1862G>A p.G621E | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV52748616; called by muse, mutect2, varscan2
- FAM135B | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 114/176 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs747996856, COSV52748628; called by muse, mutect2, varscan2
- FAM53A | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV57403159; called by muse, mutect2
- FAM98C | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1213856812, COSV53039630; called by muse, varscan2
- FAP | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV51862535; called by muse, mutect2, varscan2
- FAT3 | c.5474C>T p.T1825M | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs756801253, COSV53110476; called by muse, mutect2, varscan2
- FCAR | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as COSV62029575; called by muse, mutect2, varscan2
- FERMT1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.608); catalogued as rs151300234; called by muse, mutect2, varscan2
- FLRT2 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs751520518, COSV58143981, COSV58144150; called by muse, mutect2, varscan2
- GABRG1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV54950130, COSV99778230; called by muse, mutect2, varscan2
- GALNT13 | c.1489C>T p.H497Y | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV67235377; called by muse, mutect2, varscan2
- GALNTL5 | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV67180988; called by muse, mutect2, varscan2
- GATAD2A | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs769597782, COSV53066058; called by muse, mutect2, varscan2
- GCSAML | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867795960, COSV63577305; called by muse, mutect2, varscan2
- GIMAP6 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV61032627; called by muse, mutect2
- GOLGA5 | c.320C>A p.S107* | Nonsense Mutation (SNP) | VAF 30/66 reads (45%) | catalogued as COSV50835232; called by muse, mutect2, varscan2
- GPR6 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51573258; called by muse, mutect2, varscan2
- GPR87 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs1368040958, COSV53464266; called by muse, mutect2, varscan2
- GRIK2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV59764070; called by muse, mutect2, varscan2
- GRIN2B | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74207423; called by muse, mutect2, varscan2
- GYPA | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.355); catalogued as rs267600027, COSV51624613, COSV51635670; called by muse, mutect2, varscan2
- HEATR6 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.048); catalogued as COSV51748721; called by muse, mutect2, varscan2
- HELB | c.2896C>T p.P966S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV56075073; called by muse, mutect2, varscan2
- HLF | c.476A>T p.N159I | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); catalogued as COSV56831669; called by muse, mutect2, varscan2
- HTR3D | c.1097G>A p.G366E (on ENST00000382489 / NM_001163646.2; = p.G191E on NM_182537.3) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.096); catalogued as rs764286325, COSV61913836; called by muse, mutect2
- HUS1B | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as rs1160417759, COSV57871053; called by muse, mutect2, varscan2
- IFNA16 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); catalogued as COSV66510475; called by muse, mutect2, varscan2
- IFNA5 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 65/85 reads (76%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV52386715, COSV52387456; called by muse, mutect2, varscan2
- IFT88 | c.2480G>A p.G827E (on ENST00000319980 / NM_001318493.2; = p.G818E on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs771024026, COSV60676620; called by muse, mutect2, varscan2
- IGF2BP1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV51735085; called by muse, mutect2, varscan2
- IGLV1-47 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 186/342 reads (54%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.255); catalogued as rs181574862; called by muse, mutect2, varscan2
- IGSF1 | c.2584G>A p.D862N | Missense Mutation (SNP) | VAF 116/208 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs772636261, COSV63839685; called by muse, mutect2, varscan2
- IGSF5 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as rs769443272, COSV66031203; called by muse, mutect2, varscan2
- IL18R1 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs749556086, COSV52126166; called by mutect2, varscan2
- ILDR1 | c.1313C>T p.P438L (on ENST00000344209 / NM_001199799.2; = p.P394L on NM_175924.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56553119; called by muse, mutect2, varscan2
- IMPA2 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as rs1218047852, COSV52321099; called by muse, mutect2, varscan2
- IQGAP2 | c.2749A>C p.T917P | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV57180301; called by muse, mutect2, varscan2
- IQSEC1 | c.2579C>T p.S860F | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56228130; called by muse, mutect2, varscan2
- IQUB | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs757720186, COSV61242000; called by muse, mutect2, varscan2
- ISG20 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as rs1567122966, COSV60144409; called by muse, mutect2, varscan2
- ITGAM | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.306); catalogued as COSV54941524; called by muse, mutect2, varscan2
- ITPRID2 | c.713-1G>A p.X238_splice | Splice Site (SNP) | VAF 6/66 reads (9%) | catalogued as COSV57475676; called by muse, mutect2
- KAAG1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.414); catalogued as COSV51240019; called by muse, mutect2, varscan2
- KALRN | c.6946G>A p.D2316N (on ENST00000360013 / NM_001024660.4; = p.D619N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs775753465, COSV52259278; called by muse, mutect2, varscan2
- KCNH4 | c.1706C>T p.S569L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52916181; called by muse, mutect2, varscan2
- KCNH5 | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59763049; called by muse, mutect2, varscan2
- KCNH6 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs560791257, COSV59006932; called by muse, mutect2, varscan2
- KDR | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV55774079, COSV99818211; called by muse, mutect2, varscan2
- KDR | c.2638C>T p.R880* | Nonsense Mutation (SNP) | VAF 26/42 reads (62%) | catalogued as COSV55774091; called by muse, mutect2, varscan2
- KHDRBS2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55429110; called by muse, mutect2, varscan2
- KIAA1109 | c.12275C>T p.P4092L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV52689011; called by muse, mutect2, varscan2
- KIAA2013 | c.766A>T p.T256S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV64861120; called by muse, mutect2, varscan2
- KIF16B | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755037043, COSV61702209; called by muse, mutect2, varscan2
- KIF18A | c.395T>G p.V132G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54186937; called by muse, mutect2, varscan2
- KIF2A | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV66946534; called by muse, mutect2, varscan2
- KIF6 | c.1899C>G p.D633E | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV54691256; called by muse, mutect2, varscan2
- KIR2DL4 | c.907C>T p.R303C (on ENST00000396284; = p.R264C on NM_001080772.2) | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs748541591, COSV58497181; called by muse, mutect2
- KLHL22 | c.1670G>A p.G557D | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.469); catalogued as COSV56733758; called by muse, mutect2, varscan2
- KLHL24 | c.1753C>T p.H585Y | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54428328; called by muse, mutect2, varscan2
- KLK9 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV51594196; called by muse, mutect2, varscan2
- KRT37 | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99845467; called by muse, mutect2, varscan2
- LCE3E | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.01); catalogued as COSV64232204; called by muse, mutect2, varscan2
- LELP1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 134/217 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); catalogued as rs761668608, COSV64202571; called by muse, mutect2, varscan2
- LEPR | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60762544; called by muse, mutect2, varscan2
- LEPR | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.151); catalogued as rs1163084980, COSV100756589, COSV60762572; called by muse, mutect2, varscan2
- LIMCH1 | c.3025G>A p.G1009R | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV58294199; called by muse, mutect2, varscan2
- LRG1 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as rs764428545, COSV56705635; called by muse, mutect2, varscan2
- LRIG1 | c.3209C>T p.P1070L | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.081); catalogued as COSV99833728; called by muse, mutect2, varscan2
- LRP1B | c.11094C>G p.D3698E | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101249923, COSV67264569; called by muse, mutect2
- LRP1B | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867777706, COSV101256729; called by muse, mutect2, varscan2
- LRP1B | c.1441G>A p.G481R | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101257446, COSV67267892; called by muse, mutect2, varscan2
- LRRN2 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 133/200 reads (67%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.94); catalogued as COSV65783716; called by muse, mutect2, varscan2
- MAGEB18 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57464880; called by muse, mutect2, varscan2
- MAGEB6 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs775285937, COSV66872928; called by muse, mutect2, varscan2
- MCTP2 | c.2632C>T p.L878F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs1360313514, COSV100752616, COSV63296794; called by muse, mutect2, varscan2
- MDN1 | c.12712C>T p.R4238* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as rs775201570, COSV65528755; called by muse, mutect2, varscan2
- MDN1 | c.6851C>T p.P2284L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV65528761; called by muse, mutect2, varscan2
- MEFV | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV54823122; called by muse, mutect2, varscan2
- MERTK | c.2897G>A p.G966E | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV54934701, COSV99774278; called by muse, mutect2, varscan2
- METTL16 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV99563396; called by muse, mutect2, varscan2
- METTL7B | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57700006; called by muse, mutect2, varscan2
- MFSD11 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV60622565; called by muse, mutect2, varscan2
- MICAL3 | c.3256G>T p.E1086* | Nonsense Mutation (SNP) | VAF 9/91 reads (10%) | catalogued as COSV71588841; called by muse, mutect2, varscan2
- MIER2 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV53393961; called by muse, mutect2, varscan2
- MKNK1 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57862680; called by muse, mutect2, varscan2
- MLIP | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51434593; called by muse, mutect2, varscan2
- MOV10 | c.1702C>T p.R568W | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as rs140221891, COSV100659568; called by muse, mutect2, varscan2
- MRTFB | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV57961000; called by muse, mutect2
- MSLN | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs1192636251, COSV53505549; called by muse, mutect2, varscan2
- MTMR1 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 26/42 reads (62%) | catalogued as COSV100953094; called by muse, mutect2, varscan2
- MTMR4 | c.1600C>T p.L534F | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60202957; called by muse, mutect2, varscan2
- MTNR1B | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV57068386; called by muse, mutect2, varscan2
- MTUS2 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV70916614, COSV70916668; called by muse, mutect2, varscan2
- MUC16 | c.38336G>A p.S12779N | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.069); catalogued as COSV67487984; called by muse, mutect2, varscan2
- MUC16 | c.19439G>A p.G6480E | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.595); catalogued as COSV67487989; called by muse, mutect2, varscan2
- MUC16 | c.16937C>T p.S5646F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.46); catalogued as rs759976473, COSV67454946; called by muse, mutect2, varscan2
- MUC16 | c.10097C>T p.S3366F | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.757); catalogued as COSV67488011; called by muse, mutect2, varscan2
- MUC16 | c.1629G>A p.M543I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV67488017; called by muse, mutect2, varscan2
- MVB12A | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57679602; called by muse, mutect2, varscan2
- MYH8 | c.3158G>A p.R1053K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV67960417; called by muse, mutect2, varscan2
- NATD1 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV67541291; called by muse, mutect2, varscan2
- NCKAP1L | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV53211339; called by muse, mutect2, varscan2
- NCOA5 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs1459012457, COSV51646939; called by muse, mutect2, varscan2
- NCOA6 | c.1816C>T p.L606F | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV62867164; called by muse, mutect2
- NEBL | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV65805296; called by muse, mutect2, varscan2
- NEU4 | c.40G>A p.E14K (on ENST00000391969 / NM_001167602.3; = p.E26K on NM_080741.4) | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs200948491, COSV57989900; called by muse, mutect2, varscan2
- NGF | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV65688547; called by muse, mutect2, varscan2
- NLRC3 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs760696004, COSV57094932; called by muse, mutect2, varscan2
- NLRP11 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.971); catalogued as rs867394411, COSV64086450; called by muse, mutect2, varscan2
- NLRP5 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537471101, COSV66762321; called by muse, mutect2, varscan2
- NPY2R | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61529386; called by muse, mutect2, varscan2
- NRK | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54604805; called by muse, mutect2, varscan2
- NUP153 | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV50447682, COSV50461326; called by muse, mutect2, varscan2
- NUP210L | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 54/415 reads (13%) | catalogued as rs142024728, COSV55155852; called by muse, mutect2, varscan2
- NUTM1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs374262850, COSV61545783, COSV61548336; called by muse, mutect2, varscan2
- NXPH3 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV60872430; called by muse, mutect2, varscan2
- NYNRIN | c.2218C>T p.Q740* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV66844559; called by muse, mutect2, varscan2
- OR12D2 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV65826283, COSV65829881; called by muse, mutect2, varscan2
- OR2A25 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV68717246; called by muse, mutect2, varscan2
- OR2L8 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs565612069, COSV100594400, COSV61727112; called by muse, mutect2, varscan2
- OR2M2 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 277/437 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as COSV62898353, COSV62898618; called by muse, mutect2, varscan2
- OR2M2 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 40/316 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62899222; called by muse, mutect2, varscan2
- OR2T10 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 114/195 reads (58%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as COSV57898121; called by muse, mutect2, varscan2
- OR2T12 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 81/144 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs758367528, COSV58779183; called by muse, mutect2, varscan2
- OR52N1 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 52/72 reads (72%) | catalogued as rs548980477, COSV57693572; called by muse, mutect2, varscan2
- ORC2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV52241112; called by muse, mutect2, varscan2
- OTOP3 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV60914753; called by muse, mutect2, varscan2
- PADI2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64946521; called by muse, mutect2, varscan2
- PAEP | c.490C>A p.H164N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.678); catalogued as COSV52986141; called by muse, mutect2, varscan2
- PAN3 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1222937477, COSV66710711; called by muse, mutect2, varscan2
- PCDH15 | c.4816G>A p.E1606K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated, low confidence (0.41); catalogued as COSV100904366, COSV64727525; called by muse, mutect2, varscan2
- PCDH17 | c.2641G>A p.D881N | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64978152; called by muse, mutect2, varscan2
- PCDHAC1 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782166106, COSV53865699; called by muse, mutect2, varscan2
- PCDHB10 | c.1394G>A p.S465N | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53382911; called by muse, mutect2, varscan2
- PCLO | c.12352C>T p.P4118S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV61660078; called by muse, mutect2, varscan2
- PCSK1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV60735406; called by muse, mutect2, varscan2
- PDZRN4 | c.1970G>A p.G657E (on ENST00000402685 / NM_001164595.2; = p.G399E on NM_013377.4) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV54214352; called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.954); catalogued as rs529730514, COSV59012200; called by muse, mutect2, varscan2
- PHGDH | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs749449432, COSV65572226, COSV65572473; called by muse, mutect2, varscan2
- PIK3C2G | c.4040C>T p.S1347F (on ENST00000676171; = p.S1306F on NM_004570.5) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV56802318, COSV56814730; called by muse, mutect2, varscan2
- PIK3CB | c.1661A>G p.E554G | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56689383; called by muse, mutect2, varscan2
- PITPNM2 | c.2456C>T p.S819F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV54907314; called by muse, varscan2
- PLEC | c.9889C>T p.R3297* (on ENST00000322810 / NM_201380.4; = p.R3187* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 22/32 reads (69%) | catalogued as rs1554681458, COSV59684848; called by muse, mutect2, varscan2
- PLXNB1 | c.3907A>T p.R1303W | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV56493516; called by muse, mutect2, varscan2
- PLXND1 | c.3226C>T p.P1076S | Missense Mutation (SNP) | VAF 86/157 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60718595; called by muse, mutect2, varscan2
- POLR1F | c.524A>T p.D175V | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV55999421; called by muse, mutect2, varscan2
- PPFIA1 | c.2452C>T p.R818* | Nonsense Mutation (SNP) | VAF 32/68 reads (47%) | catalogued as COSV99557414; called by muse, varscan2
- PPP4R4 | c.1716A>G p.E572= | Splice Region (SNP) | VAF 9/26 reads (35%) | catalogued as rs867119130, COSV58557523; called by muse, mutect2, varscan2
- PRDM16 | c.787G>A p.G263S | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1478144781, COSV54605360; called by muse, mutect2, varscan2
- PRUNE2 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV65046606; called by muse, mutect2, varscan2
- PSG6 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 132/306 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV51836107; called by muse, mutect2, varscan2
- PSG9 | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 116/474 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52487521; called by muse, varscan2
- PSG9 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 79/327 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52487528; called by muse, varscan2
- PSMD3 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 110/288 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.627); catalogued as rs754581065, COSV52859443; called by muse, mutect2, varscan2
- PTGS2 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV66571347; called by muse, mutect2, varscan2
- PTPRD | c.5410C>T p.Q1804* | Nonsense Mutation (SNP) | VAF 48/79 reads (61%) | catalogued as COSV61938609; called by muse, mutect2, varscan2
- RACGAP1 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.154); catalogued as COSV56700852; called by muse, mutect2, varscan2
- RAPGEF3 | c.1172G>A p.G391D (on ENST00000389212; = p.G349D on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50229297; called by muse, mutect2, varscan2
- RBM24 | c.370C>T p.P124S (on ENST00000379052 / NM_001143942.2; = p.P79S on NM_153020.2) | Missense Mutation (SNP) | VAF 156/314 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV59002939; called by muse, mutect2, varscan2
- REG3A | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100532849, COSV59411424; called by muse, mutect2, varscan2
- RELN | c.3893G>A p.G1298E | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58995139, COSV59029159; called by muse, mutect2, varscan2
- RELN | c.3116G>T p.G1039V | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59029166; called by muse, mutect2, varscan2
- RGS8 | c.416C>T p.S139F (on ENST00000367556 / NM_001369564.2; = p.S157F on NM_033345.3) | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV51114910; called by muse, mutect2, varscan2
- ROBO1 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV71970243; called by muse, mutect2, varscan2
- ROBO2 | c.161C>G p.A54G | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV59915228, COSV59933924; called by muse, mutect2, varscan2
- ROS1 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV63860496; called by muse, mutect2, varscan2
- RTKN2 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 68/130 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV59524175; called by muse, mutect2, varscan2
- SALL1 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868718687, COSV51753329, COSV51757244; called by muse, mutect2, varscan2
- SDK1 | c.6244G>A p.G2082R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1170795893, COSV67385516; called by muse, mutect2, varscan2
- SELENOP | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72484768; called by muse, mutect2, varscan2
- SERPINA3 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV67586978; called by muse, mutect2, varscan2
- SHROOM3 | c.5935C>T p.P1979S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.123); catalogued as rs747031600, COSV56037856; called by muse, mutect2
- SIGLEC10 | c.1498G>A p.G500R | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs554914804, COSV59483043, COSV59488057; called by muse, mutect2, varscan2
- SIM1 | c.1274G>A p.R425K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.227); catalogued as rs866010754, COSV53495862; called by muse, mutect2
- SLC10A4 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs761069841, COSV56719685; called by muse, mutect2, varscan2
- SLC17A2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV55350357; called by muse, mutect2, varscan2
- SLC26A11 | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV63281001; called by muse, mutect2, varscan2
- SLC34A2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65942867; called by muse, mutect2, varscan2
- SLC9A4 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 21/98 reads (21%) | catalogued as rs571221714, COSV54834023; called by muse, mutect2, varscan2
- SLC9A5 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV55364406; called by muse, mutect2, varscan2
- SLCO1B3 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs375847286; called by muse, mutect2, varscan2
- SPEF2 | c.4991C>T p.S1664F | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.048); catalogued as rs377148150; called by muse, mutect2, varscan2
- SPEG | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56678077; called by muse, mutect2, varscan2
- SPEN | c.6853C>T p.P2285S | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV65366232; called by muse, mutect2, varscan2
- SPTAN1 | c.3092C>T p.S1031F | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV63989421; called by muse, mutect2, varscan2
- SSH1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV58459433; called by muse, mutect2
- STARD6 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 88/152 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749075638, COSV100323434; called by muse, mutect2, varscan2
- STARD6 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 85/148 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1257511221, COSV100323399; called by muse, mutect2, varscan2
- STAT3 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.305); catalogued as rs1456534236, COSV52892398; called by muse, mutect2, varscan2
- STAT4 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs757999757, COSV61829516; called by muse, mutect2, varscan2
- STAT5B | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV53185444; called by muse, mutect2, varscan2
- STK38 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV57709387; called by muse, mutect2, varscan2
- STXBP5L | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56531086; called by muse, mutect2, varscan2
- SYCP2L | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as COSV51656869; called by muse, mutect2, varscan2
- TAGAP | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1006817176, COSV57852926; called by muse, mutect2, varscan2
- TAS1R1 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as rs763740735, COSV60229829; called by muse, mutect2, varscan2
- TBX1 | c.843C>T p.I281= | Splice Region (SNP) | VAF 27/51 reads (53%) | catalogued as COSV60355057; called by muse, mutect2, varscan2
- TBX18 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63737874; called by muse, mutect2, varscan2
- TENT2 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1360837526, COSV57139068; called by muse, mutect2, varscan2
- TFEC | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55406130; called by muse, mutect2, varscan2
- THEG | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61074753; called by muse, mutect2, varscan2
- TKTL2 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149496837; called by muse, mutect2, varscan2
- TMC2 | c.1724G>T p.W575L | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62657382; called by muse, mutect2
- TMEM132B | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs780350068, COSV54743304; called by muse, mutect2, varscan2
- TMEM132D | c.3214G>A p.D1072N | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV67162067; called by muse, mutect2, varscan2
- TMEM70 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1421542235, COSV53023857; called by muse, mutect2, varscan2
- TMPRSS11B | c.687G>A p.K229= | Splice Region (SNP) | VAF 5/45 reads (11%) | catalogued as COSV60291749; called by muse, mutect2, varscan2
- TMTC3 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57125985; called by muse, mutect2, varscan2
- TNFRSF13B | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55429636; called by muse, mutect2, varscan2
- TNS2 | c.1637G>A p.G546E (on ENST00000314250 / NM_170754.4; = p.G556E on NM_015319.2) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV58581272; called by muse, mutect2, varscan2
- TOM1 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as rs747180894, COSV65899546; called by muse, mutect2, varscan2
- TOP3B | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV64118984; called by muse, mutect2, varscan2
- TPP2 | c.3292A>G p.M1098V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs754206222, COSV65754481; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPTE | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1255945263; called by muse, mutect2, varscan2
- TRANK1 | c.7950G>A p.M2650I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV57161807; called by muse, mutect2, varscan2
- TRIM36 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV56692804; called by muse, mutect2, varscan2
- TRPC6 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60259685; called by muse, mutect2, varscan2
- TRPS1 | c.2125G>C p.E709Q (on ENST00000220888 / NM_001330599.2; = p.E722Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/202 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV55257972; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54651779; called by muse, mutect2, varscan2
- TTBK2 | c.3161C>A p.P1054Q | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV51161176, COSV51174974; called by muse, mutect2, varscan2
- TTN | c.34849C>T p.P11617S (on ENST00000591111; = p.P10690S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | PolyPhen benign (0.082); catalogued as COSV60288985; called by muse, mutect2
- TTN | c.31330G>A p.E10444K (on ENST00000591111; = p.E9517K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/123 reads (23%) | PolyPhen probably damaging (0.953); catalogued as COSV60288998; called by muse, mutect2, varscan2
- TTN | c.12772G>A p.E4258K (on ENST00000591111; = p.E4212K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | catalogued as COSV60318393; called by muse, mutect2, varscan2
- TTN | c.7838G>A p.G2613E (on ENST00000591111; = p.G2567E on NM_003319.4) | Missense Mutation (SNP) | VAF 23/72 reads (32%) | PolyPhen possibly damaging (0.787); catalogued as COSV60289007; called by muse, mutect2, varscan2
- TUBA1A | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV55498738; called by muse, mutect2, varscan2
- TUFM | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV57949676; called by muse, mutect2, varscan2
- UBN1 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 137/399 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs200541080; called by muse, mutect2, varscan2
- UGT2B7 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV59441967; called by muse, mutect2, varscan2
- UNC79 | c.7229C>T p.S2410F (on ENST00000393151 / NM_001346218.2; = p.S2233F on NM_020818.5) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs998192270, COSV56401543; called by muse, mutect2, varscan2
- USP29 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54242480; called by muse, mutect2, varscan2
- WDR17 | c.3890C>T p.S1297F | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54581765; called by muse, mutect2, varscan2
- WNK4 | c.3277G>A p.E1093K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1393704293, COSV99890324; called by muse, mutect2, varscan2
- XDH | c.3644C>T p.S1215F | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65146734, COSV65147376, COSV65150868; called by muse, mutect2, varscan2
- XIRP2 | c.3045G>A p.M1015I (on ENST00000628543; = p.M1190I on NM_152381.6) | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54728570; called by muse, mutect2, varscan2
- YEATS2 | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 78/137 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59371527; called by muse, mutect2, varscan2
- ZFP28 | c.1652A>G p.H551R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56737761; called by muse, mutect2, varscan2
- ZFP64 | c.871T>C p.F291L | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.489); catalogued as COSV53803092; called by muse, mutect2, varscan2
- ZIC4 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1342760692, COSV67173763; called by muse, mutect2, varscan2
- ZNF468 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54696570; called by muse, mutect2
- ZNF502 | c.491T>G p.F164C | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56074850; called by muse, mutect2
- ZNF536 | c.3409G>A p.G1137R | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.216); catalogued as COSV62832684; called by muse, mutect2, varscan2
- ZNF862 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99783486; called by muse, mutect2, varscan2
- ZP4 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV63913233; called by muse, mutect2
- ZSCAN5B | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.575); catalogued as rs769399458, COSV61999756; called by muse, mutect2, varscan2
- CYFIP1 | c.2102A>G p.Q701R | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRMPD2B | n.1299-1G>A | Splice Site (SNP) | VAF 11/21 reads (52%) | called by mutect2, varscan2
- GPR107 | c.386+5_386+8del p.X129_splice | Splice Site (DEL) | VAF 7/51 reads (14%) | called by pindel, varscan2
- ABCC6 | c.3741C>T p.P1247= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV52747185; called by muse, mutect2, varscan2
- AC004997.1 | c.1362C>T p.F454= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs1481990970, COSV57576856; called by muse, mutect2, varscan2
- AC136428.1 | c.108C>T p.S36= | Silent (SNP) | VAF 34/225 reads (15%) | catalogued as rs1379698110, COSV71169265; called by muse, mutect2, varscan2
- ACACB | c.1056C>T p.G352= | Silent (SNP) | VAF 90/344 reads (26%) | catalogued as COSV58135616; called by muse, mutect2, varscan2
- ACAN | c.4719G>A p.R1573= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV61367026; called by muse, mutect2, varscan2
- ACSM1 | c.1164C>T p.F388= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as rs267604442, COSV54634473; called by muse, mutect2, varscan2
- ADAD1 | c.96G>A p.T32= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs755853675, COSV56641340; called by muse, mutect2, varscan2
- ADAMTS20 | c.5001A>C p.S1667= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as COSV67137789; called by muse, mutect2, varscan2
- ADH1C | c.1127G>A p.*376= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV72892970; called by muse, varscan2
- AFTPH | c.705C>T p.A235= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99480708; called by muse, mutect2, varscan2
- ALPL | c.276C>T p.F92= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV66380644; called by muse, mutect2, varscan2
- ANKLE1 | c.825C>T p.F275= (on ENST00000394458; = p.F221= on NM_152363.6) | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as rs200796739, COSV63920355; called by muse, mutect2, varscan2
- APLP1 | c.1695G>A p.E565= (on ENST00000221891 / NM_001024807.3; = p.E564= on NM_005166.4) | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV55706428; called by muse, varscan2
- ARF5 | c.204G>T p.V68= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as COSV50001918; called by muse, mutect2, varscan2
- ARHGEF37 | c.1401G>A p.T467= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs1055194861, COSV61370060; called by muse, mutect2, varscan2
- ARID2 | c.2952C>T p.V984= | Silent (SNP) | VAF 49/145 reads (34%) | catalogued as COSV57612821; called by muse, mutect2, varscan2
- ATP10D | c.1275C>T p.I425= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs753814845, COSV56712202; called by muse, mutect2
- ATP13A5 | c.2226G>A p.V742= | Silent (SNP) | VAF 70/123 reads (57%) | catalogued as COSV60874212; called by muse, mutect2, varscan2
- BAAT | c.246G>A p.L82= | Silent (SNP) | VAF 94/127 reads (74%) | catalogued as COSV52290631; called by muse, mutect2, varscan2
- BCO1 | c.373C>T p.L125= | Silent (SNP) | VAF 55/181 reads (30%) | catalogued as rs972542317, COSV50732816; called by muse, mutect2, varscan2
- BRD8 | c.3270C>T p.S1090= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV99648355; called by muse, mutect2, varscan2
- C1R | c.405C>T p.S135= (on ENST00000536053 / NM_001354346.2; = p.S121= on NM_001733.7) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV56925141; called by muse, mutect2, varscan2
- C2 | c.621C>T p.P207= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as COSV54962223; called by muse, mutect2, varscan2
- CACNA1D | c.3537C>T p.A1179= (on ENST00000350061 / NM_001128840.3; = p.A1199= on NM_000720.4) | Silent (SNP) | VAF 46/205 reads (22%) | catalogued as COSV55446488; called by muse, mutect2, varscan2
- CATSPERB | c.1113C>T p.Y371= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as COSV56433287; called by muse, mutect2, varscan2
- CD93 | c.534C>T p.F178= | Silent (SNP) | VAF 65/131 reads (50%) | catalogued as COSV55663075; called by muse, mutect2, varscan2
- CDH18 | c.1701C>A p.P567= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV56946592, COSV56954100; called by muse, mutect2, varscan2
- CELA2A | c.603C>T p.I201= | Silent (SNP) | VAF 70/186 reads (38%) | catalogued as COSV62747972; called by muse, mutect2, varscan2
- CFH | c.1374G>A p.G458= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV66412280; called by muse, mutect2
- CFHR2 | c.555G>A p.E185= | Silent (SNP) | VAF 93/161 reads (58%) | catalogued as COSV66382017; called by muse, mutect2, varscan2
- CHD3 | c.291C>A p.T97= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV57879363; called by muse, mutect2, varscan2
- CHD5 | c.1878C>T p.I626= | Silent (SNP) | VAF 72/154 reads (47%) | catalogued as rs777063752, COSV52412532; called by muse, mutect2, varscan2
- CHN1 | c.490C>T p.L164= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV69298191; called by muse, mutect2, varscan2
- CMTM4 | c.393C>T p.F131= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV58063516; called by muse, mutect2
- CNGA3 | c.1911G>A p.L637= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV55627493; called by muse, mutect2, varscan2
- CPNE4 | c.417G>A p.G139= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV70197630; called by muse, mutect2, varscan2
- CSMD1 | c.5577C>T p.I1859= (on ENST00000520002; = p.I1858= on NM_033225.6) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs764196363, COSV59372018; called by muse, mutect2
- CSMD1 | c.3027C>T p.I1009= (on ENST00000520002; = p.I1008= on NM_033225.6) | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV59372050; called by muse, mutect2
- CSN3 | c.120G>A p.Q40= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV59244829; called by muse, mutect2, varscan2
- CYP4F11 | c.1419C>T p.F473= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs149231661; called by muse, mutect2, varscan2
- DDX46 | c.2892C>T p.A964= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs138063978; called by muse, mutect2, varscan2
- DEFA6 | c.210C>T p.F70= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs1002623522, COSV52406190; called by muse, mutect2, varscan2
- DNA2 | c.243C>T p.I81= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV64429886; called by muse, mutect2, varscan2
- DNAH5 | c.5106C>T p.S1702= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV54231297; called by muse, mutect2, varscan2
- DOCK5 | c.1374G>A p.G458= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as COSV52409465; called by muse, mutect2, varscan2
- DPYS | c.1476C>T p.P492= | Silent (SNP) | VAF 74/116 reads (64%) | catalogued as rs1316642757, COSV60912797; called by muse, mutect2, varscan2
- DRD5 | c.1302C>T p.F434= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs750699062, COSV58577544; called by muse, mutect2
- EDAR | c.288C>T p.F96= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV51507005; called by muse, mutect2, varscan2
- ERICH3 | c.3213G>A p.R1071= | Silent (SNP) | VAF 68/152 reads (45%) | catalogued as rs866623762; called by muse, mutect2, varscan2
- FBN2 | c.1152G>A p.T384= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs267600336, COSV52519333; ClinVar: likely benign; called by muse, mutect2, varscan2
- FCGBP | c.9087C>T p.F3029= | Silent (SNP) | VAF 52/310 reads (17%) | called by muse, mutect2, varscan2
- FCGBP | c.5484C>T p.F1828= | Silent (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- FCRL4 | c.909G>A p.G303= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as COSV54865744; called by muse, mutect2, varscan2
- FFAR3 | c.342C>T p.F114= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as rs1456653202, COSV100588204; called by muse, varscan2
- FIS1 | c.231G>T p.L77= | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as COSV56192004; called by muse, mutect2, varscan2
- FSTL4 | c.1437G>A p.T479= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs377420733; called by muse, mutect2, varscan2
- GBP3 | c.825C>T p.S275= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV52519713; called by muse, mutect2, varscan2
- GNE | c.1921T>C p.L641= (on ENST00000396594 / NM_001128227.3; = p.L610= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV64952817; called by muse, mutect2, varscan2
- GPRC6A | c.1872G>A p.V624= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV59951787, COSV59955462; called by muse, mutect2, varscan2
- GRM2 | c.1161C>T p.A387= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as rs1222377274, COSV56587027; called by muse, mutect2, varscan2
- GRM8 | c.759C>T p.I253= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as rs370965431; called by muse, mutect2, varscan2
- HEATR6 | c.3078C>T p.V1026= | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as COSV51748712; called by muse, mutect2, varscan2
- HTR3B | c.1176C>T p.L392= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV52747156; called by muse, mutect2, varscan2
- IGHD | c.123C>T p.T41= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs1332545903, COSV66655078; called by muse, mutect2, varscan2
- IGHE | c.171C>T p.A57= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs782132756; called by muse, mutect2, varscan2
- IGHV3-23 | c.117C>T p.L39= | Silent (SNP) | VAF 93/600 reads (16%) | catalogued as rs782443110; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1461C>T p.F487= | Silent (SNP) | VAF 40/62 reads (65%) | catalogued as rs768493681, COSV61148434; called by muse, mutect2, varscan2
- INSYN2A | c.753G>A p.T251= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs539100904, COSV54753142; called by muse, mutect2, varscan2
- ITGA5 | c.1551G>A p.G517= | Silent (SNP) | VAF 47/154 reads (31%) | catalogued as COSV53220224; called by muse, mutect2, varscan2
- ITGAX | c.2280C>T p.Y760= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV51650479; called by muse, mutect2, varscan2
- ITGB6 | c.876C>T p.L292= | Silent (SNP) | VAF 18/190 reads (9%) | catalogued as COSV51797845; called by muse, mutect2
- KCNB2 | c.2382C>T p.F794= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV73049860, COSV73050946; called by muse, mutect2, varscan2
- KMT2D | c.3282C>T p.L1094= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1045405216, CD138465, COSV56478551; called by muse, mutect2, varscan2
- KRT37 | c.1314G>A p.G438= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99845464; called by muse, mutect2, varscan2
- KRTAP5-9 | c.153C>T p.A51= | Silent (SNP) | VAF 139/238 reads (58%) | catalogued as COSV73200260; called by muse, mutect2, varscan2
- LAMA2 | c.981G>A p.Q327= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV70353560; called by muse, mutect2, varscan2
- LCT | c.1911G>A p.V637= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV51556181; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.201C>T p.I67= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV53284899; called by muse, mutect2, varscan2
- LRIG1 | c.3210C>T p.P1070= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs576152489, COSV56243733; called by muse, mutect2, varscan2
- MAN2B2 | c.315G>A p.L105= | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as COSV53456204; called by muse, mutect2, varscan2
- MAPK3 | c.942C>T p.N314= | Silent (SNP) | VAF 66/221 reads (30%) | catalogued as COSV53776110; called by muse, mutect2, varscan2
- MARCHF1 | c.390C>T p.F130= (on ENST00000274056; = p.F113= on NM_017923.4) | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1436299421, COSV56821826; called by muse, mutect2
- MCCC2 | c.585C>T p.F195= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV60156517; called by muse, mutect2, varscan2
- MESD | c.646C>T p.L216= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV55726293; called by muse, mutect2, varscan2
- MINAR1 | c.2362C>T p.L788= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV59585847; called by muse, mutect2, varscan2
- MOV10 | c.1701C>T p.L567= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100659566; called by muse, mutect2, varscan2
- MSR1 | c.195C>T p.I65= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs768942318, COSV50528601; called by muse, mutect2, varscan2
- MTG2 | c.1080G>A p.R360= | Silent (SNP) | VAF 50/89 reads (56%) | catalogued as COSV63694652; called by muse, mutect2, varscan2
- MTMR1 | c.1830T>G p.P610= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as COSV100953093; called by muse, mutect2, varscan2
- MTMR6 | c.801G>A p.Q267= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV67809484; called by muse, mutect2, varscan2
- MUC3A | c.8067C>T p.I2689= | Silent (SNP) | VAF 205/1311 reads (16%) | catalogued as COSV60222520; called by muse, varscan2
- MXRA5 | c.3339G>A p.A1113= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as rs754896583, COSV54243224, COSV54245643; called by muse, mutect2, varscan2
- MYH1 | c.5364G>A p.K1788= | Silent (SNP) | VAF 50/192 reads (26%) | catalogued as COSV56855593; called by muse, mutect2, varscan2
- MYH2 | c.2262C>T p.S754= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV55446718; called by muse, mutect2, varscan2
- MYH6 | c.2973C>T p.I991= | Silent (SNP) | VAF 87/183 reads (48%) | catalogued as rs374807345; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO19 | c.411A>G p.G137= | Silent (SNP) | VAF 13/198 reads (7%) | called by muse, mutect2
- NBEAL2 | c.5952C>T p.R1984= | Silent (SNP) | VAF 217/386 reads (56%) | catalogued as COSV52762326; called by muse, mutect2, varscan2
- NCKAP5 | c.2772G>A p.V924= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV58469737; called by muse, mutect2
- NCKAP5 | c.945C>T p.C315= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV58469744; called by muse, mutect2, varscan2
- NCKAP5L | c.3477C>T p.P1159= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100259212, COSV60132903; called by muse, mutect2
- NLRC3 | c.2793G>A p.G931= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV57094925; called by muse, mutect2, varscan2
- NLRC5 | c.771C>T p.F257= | Silent (SNP) | VAF 50/154 reads (32%) | catalogued as COSV52661583; called by muse, mutect2, varscan2
- NPR1 | c.3153C>T p.L1051= | Silent (SNP) | VAF 116/193 reads (60%) | catalogued as COSV64117645; called by muse, varscan2
- OR10G7 | c.225G>A p.T75= | Silent (SNP) | VAF 33/159 reads (21%) | catalogued as rs138227924; called by muse, mutect2, varscan2
- OR1M1 | c.924G>A p.K308= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV70036854, COSV70037447; called by muse, mutect2, varscan2
- OR2G2 | c.285C>T p.I95= | Silent (SNP) | VAF 24/183 reads (13%) | catalogued as COSV60740233, COSV60742244; called by muse, mutect2, varscan2
- OR2L2 | c.663C>T p.L221= | Silent (SNP) | VAF 33/270 reads (12%) | catalogued as COSV63547447; called by muse, mutect2, varscan2
- OR2T2 | c.39C>T p.F13= | Silent (SNP) | VAF 80/183 reads (44%) | catalogued as rs779374477, COSV61617823; called by muse, mutect2, varscan2
- OR51A2 | c.150C>T p.I50= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV66748712; called by muse, mutect2, varscan2
- OR51A4 | c.150C>T p.I50= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV66749967; called by muse, mutect2, varscan2
- OR5B12 | c.453C>T p.F151= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as rs1201627555, COSV56904145; called by muse, mutect2, varscan2
- OR6N1 | c.36C>T p.F12= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs866019279, COSV58650127; called by muse, mutect2, varscan2
- OR6V1 | c.861C>T p.I287= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs1304882762, COSV69237626; called by muse, mutect2, varscan2
- OR8B2 | c.660C>T p.F220= | Silent (SNP) | VAF 52/121 reads (43%) | catalogued as COSV66665200; called by muse, mutect2, varscan2
- ORC1 | c.1515C>T p.P505= | Silent (SNP) | VAF 21/129 reads (16%) | catalogued as COSV65364989; called by muse, mutect2, varscan2
- PACRGL | c.735C>T p.S245= (on ENST00000471979; = p.S218= on NM_145048.5) | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs915131589, COSV54844448; called by muse, mutect2
- PADI3 | c.984G>A p.R328= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV64935237; called by muse, mutect2, varscan2
- PAPPA2 | c.993G>A p.K331= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV62785047; called by muse, mutect2, varscan2
- PATJ | c.501C>T p.V167= | Silent (SNP) | VAF 53/140 reads (38%) | catalogued as COSV57170237; called by muse, mutect2, varscan2
- PCDH18 | c.2964G>A p.K988= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV61271568; called by muse, mutect2, varscan2
- PCDHA1 | c.270C>T p.I90= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV65374396; called by muse, mutect2, varscan2
- PCDHA7 | c.216G>A p.G72= | Silent (SNP) | VAF 114/269 reads (42%) | catalogued as COSV65346814; called by muse, mutect2, varscan2
- PCDHB2 | c.1941G>A p.K647= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV50592098, COSV50619117, COSV99165868; called by muse, mutect2, varscan2
- PCDHB4 | c.1677C>T p.F559= | Silent (SNP) | VAF 64/163 reads (39%) | catalogued as rs553336245, COSV52022887; called by muse, mutect2, varscan2
- PCDHGA4 | c.1074C>T p.L358= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV54015228; called by muse, mutect2
- PCDHGB1 | c.51C>T p.P17= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs771477273, COSV54015212; called by muse, mutect2, varscan2
- PDZD2 | c.2835C>T p.L945= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as rs267600601, COSV56870215; called by muse, mutect2, varscan2
- PITPNM2 | c.762C>T p.S254= | Silent (SNP) | VAF 40/236 reads (17%) | catalogued as COSV54907329; called by muse, mutect2, varscan2
- PROCR | c.429C>T p.F143= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as COSV53826700; called by muse, mutect2, varscan2
- PRR14 | c.1143G>A p.R381= | Silent (SNP) | VAF 47/145 reads (32%) | catalogued as rs774794200, COSV54913404; called by muse, mutect2, varscan2
- PTPRK | c.4173C>T p.I1391= (on ENST00000368215 / NM_001291984.2; = p.I1392= on NM_002844.4) | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as rs1169515184, COSV63890878; called by muse, mutect2, varscan2
- PTRHD1 | c.243G>A p.V81= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs147683338, COSV53231956; called by muse, mutect2, varscan2
- RNASET2 | c.663C>T p.S221= | Silent (SNP) | VAF 111/269 reads (41%) | catalogued as COSV50352008; called by muse, mutect2, varscan2
- RP1 | c.2016G>A p.K672= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs200252967, COSV55109827, COSV55124712; called by muse, mutect2, varscan2
- RYR1 | c.837C>T p.L279= | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as COSV62108268; called by muse, mutect2, varscan2
- SAT2 | c.9C>T p.S3= | Silent (SNP) | VAF 36/75 reads (48%) | catalogued as COSV52647686; called by muse, mutect2, varscan2
- SCN10A | c.4605C>T p.F1535= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs867132986, COSV71862523; called by muse, mutect2, varscan2
- SCN3A | c.1416C>T p.F472= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as COSV51805555, COSV99326033; called by muse, mutect2
- SEC16B | c.2532C>T p.S844= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV57623256; called by muse, mutect2
- SEPTIN4 | c.1026C>T p.I342= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV57899011; called by muse, mutect2, varscan2
- SEPTIN5 | c.411C>T p.F137= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as COSV63530974; called by muse, mutect2, varscan2
- SFI1 | c.3678C>T p.P1226= (on ENST00000400288 / NM_001007467.3; = p.P1195= on NM_014775.4) | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV56718680; called by muse, mutect2, varscan2
- SHANK2 | c.3642C>T p.S1214= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as rs1555153760, COSV53615417; called by muse, mutect2, varscan2
- SIGLEC1 | c.1878G>A p.V626= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV52470777; called by muse, mutect2, varscan2
- SLA | c.735C>T p.T245= (on ENST00000338087 / NM_001045556.3; = p.T285= on NM_006748.4) | Silent (SNP) | VAF 18/201 reads (9%) | catalogued as COSV55091195; called by muse, mutect2
- SLC12A8 | c.1833G>A p.V611= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as rs867615876, COSV58869812; called by muse, mutect2
- SLC13A3 | c.1011C>T p.P337= | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as rs1019299997, COSV51722024; called by muse, mutect2, varscan2
- SLC24A3 | c.672G>A p.V224= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV60129818; called by muse, mutect2, varscan2
- SLC5A2 | c.1359C>T p.F453= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as CM034975, COSV57894035; called by muse, mutect2, varscan2
- SLC6A11 | c.1359G>A p.V453= | Silent (SNP) | VAF 19/180 reads (11%) | catalogued as COSV54392968; called by muse, mutect2, varscan2
- SLC6A5 | c.1314C>T p.I438= | Silent (SNP) | VAF 59/94 reads (63%) | catalogued as COSV54231362; called by muse, mutect2, varscan2
- SLC6A7 | c.1320C>T p.I440= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV57940251; called by muse, mutect2, varscan2
- SLC9B2 | c.24T>A p.I8= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV60018112, COSV60021687; called by muse, mutect2, varscan2
- SNRNP40 | c.24G>A p.K8= | Silent (SNP) | VAF 41/87 reads (47%) | catalogued as rs201970756; called by muse, mutect2, varscan2
- SORL1 | c.492C>T p.I164= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs768016148, COSV52761135; called by muse, mutect2, varscan2
- SORL1 | c.1140G>A p.L380= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as COSV52761142; called by muse, mutect2, varscan2
- SPINT1 | c.822C>T p.I274= | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as COSV59803160; called by muse, mutect2, varscan2
- STIL | c.621C>T p.I207= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV54553021; called by muse, mutect2, varscan2
- SYNJ2 | c.2652C>T p.F884= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV62900086; called by muse, mutect2, varscan2
- SYT6 | c.579G>A p.E193= (on ENST00000610222 / NM_001366225.1; = p.E108= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs755458067, COSV65775739; called by muse, mutect2, varscan2
- TANGO6 | c.2877C>T p.I959= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV55771647; called by muse, mutect2, varscan2
- TBC1D1 | c.2901C>T p.A967= | Silent (SNP) | VAF 60/259 reads (23%) | catalogued as COSV54725736; called by muse, mutect2, varscan2
- TEAD1 | c.858C>T p.F286= | Silent (SNP) | VAF 73/143 reads (51%) | catalogued as rs200089160, COSV57570064; called by muse, mutect2, varscan2
- TELO2 | c.1371C>T p.L457= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs1424514047, COSV51980643; called by muse, mutect2, varscan2
- TF | c.549G>A p.G183= | Silent (SNP) | VAF 47/85 reads (55%) | catalogued as rs371428613, COSV53923492; called by muse, mutect2, varscan2
- TF | c.1773G>A p.E591= | Silent (SNP) | VAF 27/259 reads (10%) | catalogued as rs767755375, COSV53923501; called by muse, mutect2, varscan2
- TLE4 | c.93C>T p.S31= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs373530695; called by muse, mutect2, varscan2
- TLR5 | c.2010T>C p.C670= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV60560463; called by muse, mutect2, varscan2
- TMEM237 | c.900C>T p.I300= (on ENST00000409883 / NM_001044385.3; = p.I292= on NM_152388.4) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV53806477; called by muse, mutect2, varscan2
- TRAK2 | c.2301C>T p.L767= | Silent (SNP) | VAF 96/230 reads (42%) | catalogued as rs1169841617, COSV60274404; called by muse, mutect2, varscan2
- TRERF1 | c.2991C>T p.P997= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100551367, COSV61676956; called by muse, mutect2
- TRPM7 | c.1404C>T p.F468= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV57920891; called by muse, mutect2, varscan2
- TRPV1 | c.1887C>T p.N629= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as rs946680160, COSV51523319; called by muse, mutect2
- TTC21B | c.1095C>T p.I365= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs775319673, COSV54634298; called by muse, mutect2, varscan2
- TTN | c.92250C>T p.T30750= (on ENST00000591111; = p.T23326= on NM_003319.4) | Silent (SNP) | VAF 93/251 reads (37%) | catalogued as COSV60288932; called by muse, mutect2, varscan2
- TTN | c.78411G>A p.V26137= (on ENST00000591111; = p.V18713= on NM_003319.4) | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV60288956; called by muse, mutect2, varscan2
- UGT2B4 | c.993C>T p.I331= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as COSV59319907; called by muse, mutect2, varscan2
- UNC13C | c.1710C>T p.F570= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV52850143; called by muse, mutect2, varscan2
- USP29 | c.2496C>T p.I832= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs749381433, COSV54145949; called by muse, mutect2, varscan2
- USP29 | c.2724C>T p.I908= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as rs1303338871, COSV54142540, COSV99518597; called by muse, mutect2, varscan2
- VEPH1 | c.294G>A p.G98= | Silent (SNP) | VAF 43/68 reads (63%) | catalogued as rs543692415, COSV62881919; called by muse, mutect2, varscan2
- VSIG10 | c.936C>T p.S312= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs987635721, COSV63654242; called by muse, mutect2, varscan2
- WNK4 | c.3276G>A p.K1092= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV99890319; called by muse, mutect2, varscan2
- WNT7A | c.984C>T p.F328= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV53197279; called by muse, mutect2
- ZNF274 | c.864C>A p.T288= (on ENST00000610905; = p.T183= on NM_016324.3) | Silent (SNP) | VAF 71/289 reads (25%) | catalogued as COSV58766513; called by muse, mutect2, varscan2
- ZNF451 | c.1536C>T p.V512= | Silent (SNP) | VAF 211/384 reads (55%) | catalogued as COSV62599641; called by muse, mutect2, varscan2
- ZNF598 | c.1950C>T p.P650= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs779376448, COSV70911504; called by muse, mutect2, varscan2
- ZNF611 | c.1977C>T p.F659= | Silent (SNP) | VAF 49/146 reads (34%) | catalogued as rs779186700, COSV60542986; called by muse, mutect2, varscan2
- ZNF628 | c.348C>T p.G116= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1477313235, COSV99220004; called by muse, mutect2, varscan2
- ZNF628 | c.349C>T p.L117= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99220006; called by muse, mutect2, varscan2
- ZNF677 | c.312T>G p.P104= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV61721266; called by muse, mutect2, varscan2
- ZNF862 | c.414C>T p.S138= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99783487; called by muse, mutect2, varscan2
- ZNF862 | c.1842C>T p.I614= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV56225752; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668133 G>A | 5'Flank (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- CASR | c.1378-6218G>A | Intron (SNP) | VAF 76/127 reads (60%) | catalogued as COSV56140770; called by muse, mutect2, varscan2
- CSNK1G2 | c.*80C>T | 3'UTR (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99729894; called by muse, mutect2
- MAGEC3 | c.1728+15G>A | Intron (SNP) | VAF 34/127 reads (27%) | catalogued as COSV100025363; called by muse, mutect2, varscan2
- MAST4 | c.674+63748C>T | Intron (SNP) | VAF 16/115 reads (14%) | catalogued as COSV101282542; called by muse, mutect2, varscan2
- MIR411 | n.91C>T | RNA (SNP) | VAF 5/32 reads (16%) | catalogued as rs763178455; called by muse, mutect2, varscan2
- PCDHA3 | c.2394+44C>T | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as COSV63539279, COSV63544149; called by muse, mutect2, varscan2
- PRELID3B | c.*2C>T | 3'UTR (SNP) | VAF 22/42 reads (52%) | catalogued as rs764705389, COSV99718114; called by muse, mutect2, varscan2
- SFTA3 | n.824G>A | RNA (SNP) | VAF 31/75 reads (41%) | catalogued as COSV69490143; called by muse, mutect2, varscan2
- SNORD116-23 | n.51G>A | RNA (SNP) | VAF 63/179 reads (35%) | called by muse, mutect2, varscan2
- SPRY4 | c.-26C>T | 5'UTR (SNP) | VAF 12/36 reads (33%) | catalogued as rs753337304, COSV59986673; called by muse, mutect2, varscan2
- TTN | c.10360+2308G>A | Intron (SNP) | VAF 46/73 reads (63%) | catalogued as COSV100611890; called by muse, mutect2, varscan2
- VN1R10P | n.504C>T | RNA (SNP) | VAF 47/158 reads (30%) | called by muse, mutect2, varscan2
- XPO5 | c.*124C>T | 3'UTR (SNP) | VAF 10/142 reads (7%) | catalogued as COSV99540903; called by muse, mutect2
